Gene-level copy-number profile of tumor specimen C3L-02642-03 from CPTAC case C3L-02642, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 77.3 years (28,231 days).
Specimen C3L-02642-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6d7be91c-54f3-4691-a935-2dd26f72b809.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02642-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/8ac0e545-e467-4cab-8080-ff09f944bdee

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 10; copy number 2: 10,073; copy number 3: 5,897; copy number 4: 34,963; copy number 5: 2,542; copy number 6: 5,357; copy number 8: 21; copy number 10: 27.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,498,785–143,500,512, 2 genes: AC239859.2, LINC02799.
- chr10:30,012,803–30,115,494, 1 gene: JCAD.
- chr13:48,232,612–48,599,436, 13 genes: ITM2B, RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462.
- chr22:18,715,815–18,757,906, 2 genes: PPP1R26P4, FAM230E.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 27 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:107,957,413–108,684,774, 26 genes, copy number 10 (within-gene range 4–10): AL024507.2, AL024507.1, SNORA73, MTHFD2P3, RPL3P7, Z98200.1, OSTM1, Y_RNA, OSTM1-AS1, NR2E1, AL078596.1, SNX3, Z98742.2, RNA5SP212, Z98742.1, RNU6-1144P, AFG1L, Z98742.3, AL356121.2, AL356121.1, AL353706.1, RNU6-770P, AL139106.1, AL391646.1, FOXO3, SUMO2P8.
- chr7:159,231,435–159,233,377, 1 gene, copy number 10: PIP5K1P2.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
